Somatic mutation profile of tumor specimen TCGA-28-5218-01A (aliquot TCGA-28-5218-01A-01D-1486-08) from TCGA case TCGA-28-5218, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.2 years (23,096 days).
Specimen TCGA-28-5218-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1af0efcc-39f9-45d0-ade4-d390e2363a28.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-28-5218-10A (Blood Derived Normal), aliquot TCGA-28-5218-10A-01D-1486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4000d8fa-3f11-4a3e-9eff-8a020db39ecf

The open-access MAF lists 18 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 11, Nonsense Mutation 3, Silent 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MEN1 | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 22/48 reads (46%) | catalogued as rs1565648511, CM983963, COSV53640162; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP6V1C1 | c.717C>G p.H239Q | Missense Mutation (SNP) | VAF 89/298 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as COSV67778101; called by muse, mutect2, varscan2
- EPHA1 | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 60/403 reads (15%) | catalogued as rs1421157458, COSV51971793; called by muse, mutect2, varscan2
- HMCN1 | c.15008T>G p.V5003G | Missense Mutation (SNP) | VAF 57/331 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV54904246; called by muse, mutect2, varscan2
- LRRC6 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 202/431 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as rs1282086532, COSV51542575; called by muse, mutect2, varscan2
- MAP3K21 | c.3080T>C p.I1027T | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as rs775744374, COSV64041788; called by muse, mutect2, varscan2
- MYDGF | c.188G>A p.C63Y | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773946741, COSV53560811; called by muse, mutect2, varscan2
- NLRP5 | c.1618T>A p.W540R | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV66765075; called by muse, mutect2, varscan2
- OBSCN | c.21172C>T p.P7058S | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV62452997; called by muse, varscan2
- OTC | c.488T>C p.L163P | Missense Mutation (SNP) | VAF 69/100 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50002029; called by muse, mutect2, varscan2
- SENP5 | c.1068G>A p.W356* | Nonsense Mutation (SNP) | VAF 59/90 reads (66%) | catalogued as COSV60207875; called by muse, mutect2, varscan2
- SNRPB | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 111/233 reads (48%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.964); catalogued as rs376998028; called by muse, mutect2, varscan2
- ZBTB40 | c.1522G>T p.D508Y | Missense Mutation (SNP) | VAF 127/203 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV65145449; called by muse, mutect2, varscan2
- ZNF317 | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 77/191 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.135); catalogued as COSV56109855; called by muse, mutect2, varscan2
- INPPL1 | c.1542del p.K515Sfs*16 | Frame Shift Del (DEL) | VAF 53/109 reads (49%) | called by mutect2, pindel, varscan2
- SESN3 | c.154_157del p.A52Tfs*27 | Frame Shift Del (DEL) | VAF 64/113 reads (57%) | called by mutect2, pindel, varscan2
- FIGN | c.726C>T p.L242= | Silent (SNP) | VAF 38/85 reads (45%) | catalogued as COSV60767247; called by muse, mutect2, varscan2
- RNF40 | c.405G>A p.G135= | Silent (SNP) | VAF 17/118 reads (14%) | catalogued as COSV61215014; called by muse, mutect2, varscan2
